Somatic mutation profile of tumor specimen HCM-BROD-0716-C43-06B (aliquot HCM-BROD-0716-C43-06B-01D-A83U-36) from HCMI case HCM-BROD-0716-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 58.7 years (21,450 days).
Specimen HCM-BROD-0716-C43-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 608acc4b-c71f-477e-ba52-a8f9dafc5e18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0716-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0716-C43-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d716877-bcc6-47df-a145-d58e128b7802

The open-access MAF lists 741 somatic variants for this specimen: 472 protein-altering or splice-affecting, 240 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 432, Silent 240, Nonsense Mutation 33, Intron 14, RNA 6, 5'Flank 3, 3'UTR 3, 3'Flank 2, Splice Site 2, 5'UTR 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 122/154 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 120/152 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 105/354 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SAMD9 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 32/143 reads (22%) | catalogued as rs1186536794, COSV66076161; ClinVar: pathogenic; called by muse, varscan2
- AAAS | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 176/478 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs748222885; called by muse, varscan2
- ACACA | c.6745C>T p.R2249C | Missense Mutation (SNP) | VAF 149/531 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1165714087; called by muse, mutect2, varscan2
- ACTL8 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 227/668 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64862748; called by muse, mutect2, varscan2
- ADAM18 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs752996370, COSV55844420, COSV55851975; called by muse, mutect2, varscan2
- ADAM7 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.672); catalogued as COSV99445097; called by muse, mutect2, varscan2
- ADAMTS18 | c.2312C>T p.P771L | Missense Mutation (SNP) | VAF 112/316 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400194605; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 167/467 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as rs1205309238; called by muse, mutect2, varscan2
- ADGRL2 | c.1933G>A p.E645K (on ENST00000370717 / NM_001366005.1; = p.E632K on NM_012302.4) | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99590770; called by muse, mutect2, varscan2
- AGRN | c.5233C>T p.R1745C | Missense Mutation (SNP) | VAF 289/862 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as rs765077103; called by muse, mutect2, varscan2
- ALDH16A1 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 275/869 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs770180307; called by muse, mutect2, varscan2
- ALOX15 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 141/422 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.472); catalogued as rs755005094; called by muse, mutect2, varscan2
- ALPI | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 320/827 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV55014023; called by muse, mutect2, varscan2
- ALS2 | c.1865C>T p.S622F | Missense Mutation (SNP) | VAF 131/369 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1439273774, COSV51884319; called by muse, mutect2, varscan2
- AP2A2 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 187/589 reads (32%) | catalogued as COSV59960126; called by muse, mutect2, varscan2
- ASB18 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 406/1086 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs751717266; called by muse, mutect2, varscan2
- ASB5 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 109/304 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs774259355, COSV56673280; called by muse, mutect2, varscan2
- ASIC4 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 156/458 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as rs777793535, COSV61731810; called by muse, mutect2, varscan2
- ATP2A3 | c.2160G>A p.M720I | Missense Mutation (SNP) | VAF 241/650 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs778581081; called by muse, mutect2, varscan2
- BAZ1B | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 330/659 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as rs782409459; called by muse, mutect2, varscan2
- BRINP1 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 143/419 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1422923029, COSV56314632; called by muse, mutect2, varscan2
- BSN | c.10654G>A p.A3552T | Missense Mutation (SNP) | VAF 204/664 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs774778213, COSV99608870; called by muse, mutect2, varscan2
- BTBD8 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.819); catalogued as COSV61546128; called by muse, mutect2, varscan2
- C12orf42 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 106/360 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.047); catalogued as COSV100172484; called by muse, mutect2, varscan2
- C3 | c.2983G>A p.V995I | Missense Mutation (SNP) | VAF 179/547 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759285914, COSV55572475; called by muse, mutect2, varscan2
- CACNA1C | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 146/493 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1310223974, COSV59791416; called by muse, mutect2, varscan2
- CACNA1F | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 233/356 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as COSV59905541; called by muse, varscan2
- CACNA2D4 | c.1988G>A p.G663E | Missense Mutation (SNP) | VAF 174/518 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54950879; called by muse, mutect2, varscan2
- CCDC185 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 298/854 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV64821919; called by muse, mutect2, varscan2
- CCDC3 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 128/417 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV66560727; called by muse, mutect2, varscan2
- CCIN | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 248/648 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.765); catalogued as rs1450270569, COSV58724961; called by muse, mutect2, varscan2
- CD40LG | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs752210787, CD961880, COSV65698933; called by muse, mutect2, varscan2
- CEP170 | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 170/460 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.243); catalogued as rs577000363; called by muse, mutect2, varscan2
- CLEC14A | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 269/840 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV100643681; called by muse, mutect2, varscan2
- CLSTN3 | c.1268A>G p.Y423C | Missense Mutation (SNP) | VAF 139/451 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1204956241; called by muse, mutect2, varscan2
- CNOT10 | c.1967G>A p.R656K | Missense Mutation (SNP) | VAF 186/506 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs1219969307; called by muse, mutect2, varscan2
- CNTN4 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV61875871; called by muse, mutect2, varscan2
- COL1A2 | c.2894C>T p.P965L | Missense Mutation (SNP) | VAF 372/769 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs1437648908; called by muse, mutect2, varscan2
- COL4A4 | c.2762G>A p.G921E | Missense Mutation (SNP) | VAF 160/546 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61634894; called by muse, varscan2
- CORO7-PAM16 | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 246/704 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as COSV52110091, COSV52111311; called by muse, mutect2, varscan2
- CPT2 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 197/553 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773966429, COSV53760302; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSF1 | c.1255C>T p.L419F | Missense Mutation (SNP) | VAF 486/1294 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.837); catalogued as rs772621335; called by muse, mutect2
- CSMD3 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 61/275 reads (22%) | catalogued as COSV52186754, COSV52248040; called by muse, mutect2, varscan2
- CT47B1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 205/296 reads (69%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); catalogued as rs542629895; called by muse, mutect2, varscan2
- CYP11B2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 140/565 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1311264822; called by muse, mutect2, varscan2
- DCST1 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 282/803 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1160179576; called by muse, mutect2, varscan2
- DMD | c.1987G>A p.A663T | Missense Mutation (SNP) | VAF 105/150 reads (70%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV99918234; called by muse, mutect2, varscan2
- DNAH5 | c.7916G>A p.R2639Q | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs140968268, COSV54202500; called by muse, mutect2, varscan2
- DNAH8 | c.3296T>C p.I1099T | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs757754264; called by muse, mutect2, varscan2
- DNAH8 | c.10447G>A p.E3483K | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59470485; called by muse, mutect2, varscan2
- DOCK4 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 169/744 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV70323885; called by muse, mutect2, varscan2
- DPP10 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 149/419 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59722322; called by muse, mutect2, varscan2
- DPYS | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 156/720 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs765884757, COSV60906455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSC1 | c.2578G>A p.G860S | Missense Mutation (SNP) | VAF 213/644 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs766767693; called by muse, mutect2, varscan2
- EFCAB12 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 235/708 reads (33%) | catalogued as rs201855762; called by muse, mutect2, varscan2
- EFR3A | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 108/557 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs372996175; called by muse, mutect2, varscan2
- ELF5 | c.625G>A p.E209K (on ENST00000312319 / NM_198381.2; = p.E199K on NM_001422.4) | Missense Mutation (SNP) | VAF 101/341 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99141310; called by muse, mutect2, varscan2
- EMB | c.682T>A p.L228M | Missense Mutation (SNP) | VAF 131/398 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV100297098; called by muse, mutect2, varscan2
- EPHA1 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 655/844 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs759092209; called by muse, mutect2, varscan2
- EPYC | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 136/477 reads (29%) | catalogued as rs779578980, COSV53799693; called by muse, mutect2, varscan2
- EXOC6B | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs779466855; called by muse, mutect2, varscan2
- EYA1 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 373/775 reads (48%) | catalogued as CM980645, COSV100378534, COSV100379912, COSV58162866; called by muse, mutect2, varscan2
- FAM83B | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 99/309 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753104783, COSV60922418; called by muse, mutect2, varscan2
- FAM89B | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 630/1637 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.837); catalogued as rs1308626906; called by muse, mutect2, varscan2
- FAT3 | c.7049G>A p.R2350Q | Missense Mutation (SNP) | VAF 77/247 reads (31%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as rs1451801313; called by muse, mutect2, varscan2
- FCN1 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 114/331 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.711); catalogued as rs140379786; called by muse, mutect2, varscan2
- FHL5 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 114/191 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746596116, COSV100459801; called by muse, mutect2, varscan2
- FOLH1 | c.1900dup p.S634Ffs*15 | Frame Shift Ins (INS) | VAF 21/85 reads (25%) | catalogued as rs1446664569; called by mutect2, pindel, varscan2
- GAD2 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 88/277 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV52150771; called by muse, mutect2, varscan2
- GALNTL6 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 166/507 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.06); catalogued as COSV101560008; called by muse, mutect2, varscan2
- GDF10 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 414/747 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.704); catalogued as rs1255618926; called by muse, mutect2, varscan2
- GJA8 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 220/704 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs782515955; called by muse, mutect2, varscan2
- GJB4 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 339/864 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs200953314; called by muse, mutect2, varscan2
- GLB1L2 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 155/499 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV56995292; called by muse, mutect2, varscan2
- GPR142 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 379/1036 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1210262311; called by muse, mutect2, varscan2
- GPR61 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 227/669 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs143529971; called by muse, mutect2, varscan2
- GREB1 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 644/1139 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs375384889; called by muse, mutect2, varscan2
- GRIA1 | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 140/270 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.434); catalogued as COSV99600734; called by muse, mutect2, varscan2
- GRIN3A | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 253/796 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs1402016826, COSV100702013; called by muse, mutect2, varscan2
- GRXCR1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 229/712 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs773349384; called by muse, mutect2, varscan2
- GSG1 | c.113C>T p.S38L (on ENST00000651961 / NM_001080555.4; = p.S25L on NM_031289.5) | Missense Mutation (SNP) | VAF 176/547 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs150478386; called by muse, mutect2, varscan2
- GUCA1C | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs1265768088, COSV51712957; called by muse, mutect2, varscan2
- GUCY2D | c.1957-1G>A p.X653_splice | Splice Site (SNP) | VAF 145/445 reads (33%) | catalogued as rs61749759, CS002137, CS002138, COSV99643916; ClinVar: not provided; called by muse, mutect2, varscan2
- HCAR2 | c.1059G>A p.W353* | Nonsense Mutation (SNP) | VAF 64/596 reads (11%) | catalogued as rs765816524, COSV61024952; called by muse, varscan2
- HSPA2 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 217/606 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); catalogued as COSV99904656; called by muse, mutect2, varscan2
- IDO1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 201/615 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53713747; called by muse, mutect2, varscan2
- IGLL1 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 284/923 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs758781859, COSV50769746; called by muse, mutect2
- IL1RL2 | c.1264T>C p.F422L | Missense Mutation (SNP) | VAF 132/428 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490844923; called by muse, mutect2, varscan2
- IMPG1 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 201/413 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64059238; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV104431183, COSV67330611; called by muse, mutect2, varscan2
- KCNB2 | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 476/928 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.983); catalogued as rs140075333; called by muse, mutect2, varscan2
- KCNH6 | c.2171C>T p.S724F | Missense Mutation (SNP) | VAF 246/662 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV59005895; called by muse, mutect2, varscan2
- KIAA0825 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV56950528; called by muse, mutect2, varscan2
- KIAA0930 | c.637A>T p.K213* (on ENST00000336156 / NM_001009880.2; = p.K218* on NM_015264.2) | Nonsense Mutation (SNP) | VAF 220/662 reads (33%) | catalogued as rs780119054; called by muse, mutect2, varscan2
- KIF4B | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 200/341 reads (59%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.882); catalogued as rs541398809, COSV70528412; called by muse, mutect2, varscan2
- KIR2DL3 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as rs776687200, COSV60896036; called by muse, mutect2, varscan2
- KLHL3 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 150/273 reads (55%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.791); catalogued as COSV59051036; called by muse, mutect2, varscan2
- KMT2C | c.7703G>A p.G2568E | Missense Mutation (SNP) | VAF 517/991 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV51366586, COSV51424113; called by muse, mutect2, varscan2
- KRT31 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 297/778 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as COSV52436185; called by muse, mutect2, varscan2
- KRT34 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 129/392 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs866265957, COSV101222713, COSV67449443; called by muse, mutect2, varscan2
- KRTAP23-1 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 143/374 reads (38%) | PolyPhen benign (0.011); catalogued as rs750836659, COSV100492653; called by muse, mutect2, varscan2
- LILRB2 | c.1148T>C p.M383T | Missense Mutation (SNP) | VAF 239/652 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs1028997873; called by muse, mutect2, varscan2
- LRFN2 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 218/616 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751273503; called by muse, mutect2, varscan2
- LRP1B | c.10468C>T p.P3490S | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101261909; called by muse, mutect2, varscan2
- LTF | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 168/454 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99207231; called by muse, mutect2, varscan2
- MACF1 | c.12026A>G p.D4009G (on ENST00000372915; = p.D1942G on NM_012090.5) | Missense Mutation (SNP) | VAF 162/486 reads (33%) | catalogued as rs748658509; called by muse, varscan2
- MAGEE2 | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 265/365 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV64897995; called by muse, mutect2, varscan2
- MAOA | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs140295792, COSV58641530; called by muse, mutect2, varscan2
- MAPT | c.2222G>A p.R741K (on ENST00000262410 / NM_001377265.1; = p.R349K on NM_005910.5) | Missense Mutation (SNP) | VAF 136/539 reads (25%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.753); catalogued as COSV99291558; called by muse, mutect2, varscan2
- MARCO | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 177/558 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254250452, COSV100503572, COSV59056535; called by muse, mutect2, varscan2
- MDC1 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 399/1099 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV64526333; called by muse, mutect2, varscan2
- ME1 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs145714966; called by muse, mutect2, varscan2
- MEIOC | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV63441841; called by muse, mutect2, varscan2
- MGAT4C | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as COSV59833687; called by muse, mutect2, varscan2
- MIDEAS | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 349/1055 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs751165860, COSV54098999; called by muse, mutect2, varscan2
- MMRN1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV104392866; called by muse, mutect2, varscan2
- MXRA5 | c.6565G>A p.D2189N | Missense Mutation (SNP) | VAF 218/301 reads (72%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as rs1482162845; called by muse, mutect2, varscan2
- MYH1 | c.5671G>A p.E1891K | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56855015; called by muse, mutect2, varscan2
- MYH8 | c.3544G>A p.E1182K | Missense Mutation (SNP) | VAF 150/442 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67970669; called by muse, mutect2, varscan2
- MYLK3 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 132/393 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs1355220180; called by muse, mutect2, varscan2
- NAT10 | c.2362C>T p.P788S | Missense Mutation (SNP) | VAF 164/435 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as rs867498285; called by muse, mutect2, varscan2
- NCDN | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 311/855 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV61936231; called by muse, mutect2, varscan2
- NETO1 | c.230G>T p.R77I | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100199031; called by muse, mutect2, varscan2
- NEXMIF | c.4174C>T p.H1392Y | Missense Mutation (SNP) | VAF 212/286 reads (74%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as rs868098984; called by muse, mutect2, varscan2
- NISCH | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 319/898 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1183478558; called by muse, varscan2
- NLGN4X | c.1730G>A p.R577K | Missense Mutation (SNP) | VAF 184/283 reads (65%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV52025367; called by muse, mutect2, varscan2
- NLRP3 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 214/647 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs762512734, COSV60229623; called by muse, mutect2, varscan2
- NPHS1 | c.3569G>A p.G1190E | Missense Mutation (SNP) | VAF 96/312 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as rs1353178621, COSV62287681; called by muse, mutect2, varscan2
- NR1H2 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 406/1133 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs760182372, COSV53801555; called by muse, varscan2
- OR10D3 | c.336C>A p.C112* | Nonsense Mutation (SNP) | VAF 175/514 reads (34%) | catalogued as rs1292080091; called by muse, mutect2, varscan2
- OR13C9 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV99403468; called by muse, mutect2, varscan2
- OR2M5 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV63546077; called by muse, varscan2
- OR4D5 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 240/684 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs768699202, COSV58305938; called by muse, mutect2, varscan2
- OR4X1 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 190/572 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV60723863; called by muse, mutect2, varscan2
- OR51B2 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 65/218 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.216); catalogued as COSV60915972; called by muse, mutect2, varscan2
- OR51F2 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 136/434 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as rs767787431, COSV59063793; called by muse, mutect2, varscan2
- OR5B17 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as rs764197115; called by muse, mutect2, varscan2
- OR5H14 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs541342101, COSV71193554, COSV71194506; called by muse, mutect2, varscan2
- OR5H2 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV62351535; called by muse, mutect2, varscan2
- OTOF | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 468/879 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55522067; called by muse, mutect2, varscan2
- PAX7 | c.112G>T p.V38F | Missense Mutation (SNP) | VAF 242/770 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1351630881; called by muse, mutect2
- PCDH17 | c.2349G>A p.M783I | Missense Mutation (SNP) | VAF 270/756 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV64972304; called by muse, mutect2, varscan2
- PCDHAC1 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 198/354 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs140626189, COSV53845270; called by muse, mutect2, varscan2
- PCDHB6 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 343/595 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99172745; called by muse, mutect2, varscan2
- PCDHB8 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 106/601 reads (18%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs782235899, COSV50769178; called by muse, varscan2
- PCDHGB3 | c.2146C>T p.R716* | Nonsense Mutation (SNP) | VAF 198/359 reads (55%) | catalogued as rs1208837944, COSV53894285; called by muse, mutect2, varscan2
- PCLO | c.8024C>T p.S2675F | Missense Mutation (SNP) | VAF 110/541 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV61640639; called by muse, mutect2, varscan2
- PCLO | c.5290G>A p.G1764S | Missense Mutation (SNP) | VAF 164/712 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61629062; called by muse, mutect2, varscan2
- PCNX2 | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 184/629 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.575); catalogued as COSV50800921; called by muse, mutect2, varscan2
- PGLYRP4 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 195/562 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62834456; called by muse, mutect2, varscan2
- PID1 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 179/521 reads (34%) | PolyPhen benign (0); catalogued as COSV62475226; called by muse, mutect2, varscan2
- PIK3R5 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 218/622 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs1395300937; called by muse, varscan2
- PIK3R5 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 230/698 reads (33%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs751907609, COSV52652124; called by muse, varscan2
- PIWIL2 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 137/389 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1465787639; called by muse, mutect2, varscan2
- PKD1L1 | c.5809C>T p.H1937Y | Missense Mutation (SNP) | VAF 217/580 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56977570; called by muse, mutect2, varscan2
- PLXNC1 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs760717500, COSV51570639; called by muse, mutect2, varscan2
- POM121L2 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 169/516 reads (33%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs937423049, COSV101079309; called by muse, mutect2, varscan2
- POTEG | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 242/2228 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.33); catalogued as COSV101611993; called by muse, varscan2
- PRB2 | c.950G>C p.G317A | Missense Mutation (SNP) | VAF 139/472 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.295); catalogued as COSV101231495; called by mutect2, varscan2
- PRB2 | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 138/458 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs568468055; called by mutect2, varscan2
- PREX2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 138/570 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV55756774, COSV55797706; called by muse, mutect2, varscan2
- PRKD1 | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776034417, COSV59573695; called by muse, mutect2, varscan2
- PTGER3 | c.1081G>A p.E361K (on ENST00000628037 / NM_198717.2; = p.E370K on NM_198716.2) | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs771757558, COSV63388000; called by muse, mutect2, varscan2
- PTPRK | c.2743C>T p.R915* (on ENST00000368215 / NM_001291984.2; = p.R916* on NM_002844.4) | Nonsense Mutation (SNP) | VAF 51/80 reads (64%) | catalogued as rs1397159308, COSV63893274; called by muse, mutect2, varscan2
- PTPRR | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV51738549; called by muse, mutect2, varscan2
- PXDNL | c.1672C>T p.H558Y | Missense Mutation (SNP) | VAF 319/652 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV62500987; called by muse, mutect2, varscan2
- QRICH2 | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 246/814 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1364166103; called by muse, mutect2, varscan2
- RFX6 | c.2368G>A p.G790R | Missense Mutation (SNP) | VAF 143/291 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100264096; called by muse, mutect2, varscan2
- RGS4 | c.421A>G p.M141V | Missense Mutation (SNP) | VAF 152/464 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV104425574; called by muse, mutect2, varscan2
- RP1L1 | c.4772C>T p.P1591L | Missense Mutation (SNP) | VAF 307/906 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV66760002; called by muse, mutect2, varscan2
- RTL1 | c.3715G>A p.D1239N | Missense Mutation (SNP) | VAF 364/954 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.949); catalogued as rs775741559, COSV66017479; called by muse, mutect2, varscan2
- RTL1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 239/671 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV66016815; called by muse, mutect2, varscan2
- SCD5 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 116/288 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs762891080, COSV56726239; called by muse, varscan2
- SCN9A | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 90/317 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); catalogued as COSV100313435, COSV57610049; called by muse, mutect2, varscan2
- SEMA3E | c.1258A>G p.K420E | Missense Mutation (SNP) | VAF 168/365 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.439); catalogued as COSV57081254; called by muse, mutect2, varscan2
- SERPINB4 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868227362, COSV61984277; called by muse, mutect2, varscan2
- SHISA6 | c.1249G>A p.E417K (on ENST00000409168 / NM_001173461.1; = p.E468K on NM_207386.4) | Missense Mutation (SNP) | VAF 324/938 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs929688938, COSV69389395; called by muse, mutect2, varscan2
- SHKBP1 | c.2032C>T p.R678* | Nonsense Mutation (SNP) | VAF 392/980 reads (40%) | catalogued as rs1206915794; called by muse, mutect2, varscan2
- SLC22A1 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 261/451 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs375891889; called by muse, mutect2, varscan2
- SLC2A9 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV53328793; called by muse, mutect2, varscan2
- SLFN11 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 143/484 reads (30%) | catalogued as rs754420565; called by muse, mutect2, varscan2
- SPHKAP | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 138/432 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.335); catalogued as rs770444711; called by muse, mutect2, varscan2
- SPINK5 | c.2999C>T p.P1000L | Missense Mutation (SNP) | VAF 82/144 reads (57%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); catalogued as rs1233347708; called by muse, mutect2, varscan2
- SPN | c.153T>G p.S51R | Missense Mutation (SNP) | VAF 227/680 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1481054377; called by muse, mutect2, varscan2
- SPRED1 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 196/559 reads (35%) | catalogued as rs148646547, CM1210087, COSV54437715; called by muse, mutect2, varscan2
- TAF13 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.786); catalogued as rs766023319; called by muse, mutect2, varscan2
- TAOK1 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 122/467 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs777374325; called by muse, mutect2, varscan2
- TBCD | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 86/294 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs769827032; called by muse, mutect2, varscan2
- TCEA3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 169/572 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.094); catalogued as COSV65840931; called by muse, mutect2, varscan2
- TGM5 | c.1942G>A p.E648K (on ENST00000220420 / NM_201631.4; = p.E566K on NM_004245.4) | Missense Mutation (SNP) | VAF 160/601 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV55009673; called by muse, mutect2, varscan2
- THBS1 | c.3176C>T p.S1059L | Missense Mutation (SNP) | VAF 269/765 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as rs1339729749; called by muse, varscan2
- TNC | c.1304G>A p.S435N | Missense Mutation (SNP) | VAF 270/747 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as rs1359511347; called by muse, mutect2, varscan2
- TNFSF4 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 203/642 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as rs866439624; called by muse, mutect2, varscan2
- TNR | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 266/703 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs746751518, COSV54872462, COSV54893268; called by muse, mutect2, varscan2
- TNR | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 189/564 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.518); catalogued as rs1461282624; called by muse, mutect2, varscan2
- TOM1 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 171/557 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs746325920; called by muse, mutect2, varscan2
- TONSL | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 248/963 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV68048469; called by muse, mutect2, varscan2
- TPR | c.2227C>T p.H743Y | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV66602025; called by muse, mutect2, varscan2
- TPTE2 | c.1063C>T p.R355* (on ENST00000400230 / NM_199254.2; = p.R278* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 23/123 reads (19%) | catalogued as rs759307577; called by muse, mutect2, varscan2
- TTC24 | c.1303G>A p.G435R | Missense Mutation (SNP) | VAF 245/802 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.089); catalogued as rs1483568396; called by muse, mutect2, varscan2
- TTN | c.66680G>A p.R22227Q (on ENST00000591111; = p.R14803Q on NM_003319.4) | Missense Mutation (SNP) | VAF 118/325 reads (36%) | PolyPhen benign (0.396); catalogued as rs763316990, COSV60061049; called by muse, mutect2, varscan2
- TTN | c.51169G>A p.E17057K (on ENST00000591111; = p.E9633K on NM_003319.4) | Missense Mutation (SNP) | VAF 50/191 reads (26%) | PolyPhen probably damaging (0.994); catalogued as COSV60199420; called by muse, mutect2
- TTN | c.37579G>A p.E12527K (on ENST00000591111; = p.E5103K on NM_003319.4) | Missense Mutation (SNP) | VAF 63/183 reads (34%) | PolyPhen possibly damaging (0.54); catalogued as COSV60379055; called by muse, mutect2, varscan2
- TULP1 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 112/354 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs868771267, COSV57691716; called by muse, mutect2, varscan2
- UGT2A3 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV52360148; called by muse, mutect2, varscan2
- UNC13C | c.3781G>A p.G1261R | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV52844021; called by muse, mutect2, varscan2
- UNC5CL | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 232/708 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs767528036, COSV55109870; called by muse, mutect2, varscan2
- USH2A | c.14348C>T p.S4783F | Missense Mutation (SNP) | VAF 117/319 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs373551475; called by muse, mutect2, varscan2
- USP29 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 86/342 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.098); catalogued as rs754668181; called by muse, mutect2, varscan2
- VWA5B1 | c.3175T>C p.S1059P (on ENST00000375079; = p.S1054P on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 201/583 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs530582281; called by muse, mutect2, varscan2
- WDR87 | c.5293G>A p.E1765K | Missense Mutation (SNP) | VAF 178/515 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.029); catalogued as rs973446632; called by muse, mutect2, varscan2
- XRN2 | c.1956C>G p.F652L | Missense Mutation (SNP) | VAF 134/415 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101018323, COSV65869394; called by muse, mutect2, varscan2
- ZBTB14 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 139/405 reads (34%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.218); catalogued as rs772807095; called by muse, mutect2, varscan2
- ZDHHC22 | c.715G>C p.G239R | Missense Mutation (SNP) | VAF 263/775 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60058290; called by muse, mutect2, varscan2
- ZNF180 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.735); catalogued as rs768681387; called by muse, mutect2, varscan2
- ZNF208 | c.1087C>T p.H363Y | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101237059, COSV68106286; called by muse, mutect2, varscan2
- ZNF544 | c.140G>T p.W47L | Missense Mutation (SNP) | VAF 81/295 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as COSV99517179; called by muse, mutect2, varscan2
- ZNF560 | c.534G>A p.W178* | Nonsense Mutation (SNP) | VAF 27/117 reads (23%) | catalogued as COSV56865962; called by muse, mutect2, varscan2
- ZNF781 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.225); catalogued as rs1205986398, COSV62201508; called by muse, mutect2, varscan2
- ZNF93 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs879037548; called by muse, mutect2, varscan2
- ZNF98 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.404); catalogued as COSV63337207; called by muse, mutect2, varscan2
- ZSCAN5B | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 159/475 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV61999079; called by muse, mutect2, varscan2
- AADACL3 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 150/486 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ABCA4 | c.6572G>A p.G2191E | Missense Mutation (SNP) | VAF 127/385 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 255/788 reads (32%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ACAN | c.1750A>C p.T584P | Missense Mutation (SNP) | VAF 190/540 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ACCS | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 136/503 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADH1B | c.945G>A p.W315* | Nonsense Mutation (SNP) | VAF 71/217 reads (33%) | called by muse, mutect2, varscan2
- AL121845.3 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 261/748 reads (35%) | called by muse, mutect2, varscan2
- ALDH3A2 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ANKRD18A | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ANKRD30A | c.4076G>A p.R1359K (on ENST00000611781; = p.R1303K on NM_052997.2) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ANKRD30B | c.2639C>T p.S880F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ANKRD44 | c.2591C>T p.P864L | Missense Mutation (SNP) | VAF 216/609 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- ANPEP | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 175/569 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- APAF1 | c.332G>A p.R111K (on ENST00000551964 / NM_181861.2; = p.R100K on NM_001160.3) | Missense Mutation (SNP) | VAF 76/243 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP44 | c.1431G>A p.M477I | Missense Mutation (SNP) | VAF 206/608 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2
- ASTN2 | c.3766G>A p.D1256N (on ENST00000313400 / NM_001365069.1; = p.D1205N on NM_014010.5) | Missense Mutation (SNP) | VAF 128/377 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- BDKRB2 | c.984C>A p.N328K | Missense Mutation (SNP) | VAF 222/637 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSN | c.9403C>T p.P3135S | Missense Mutation (SNP) | VAF 329/937 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C10orf71 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 205/408 reads (50%) | called by muse, mutect2, varscan2
- C19orf18 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- C3orf80 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 380/1050 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- CACNA1G | c.2980G>A p.G994R | Missense Mutation (SNP) | VAF 159/444 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- CACNA1I | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 178/540 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1I | c.5698G>A p.G1900R | Missense Mutation (SNP) | VAF 141/402 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNA2D3 | c.2588G>A p.G863E | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CACNB1 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 201/627 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBLB | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 177/582 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CCDC157 | c.109T>C p.F37L | Missense Mutation (SNP) | VAF 326/936 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- CCDC73 | c.2714C>A p.S905* | Nonsense Mutation (SNP) | VAF 83/267 reads (31%) | called by muse, mutect2, varscan2
- CCNB3 | c.2276T>C p.V759A | Missense Mutation (SNP) | VAF 200/309 reads (65%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDC16 | c.713C>A p.A238D | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC42BPA | c.970A>G p.S324G | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- CEACAM20 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 273/760 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CEMIP | c.2851G>A p.D951N | Missense Mutation (SNP) | VAF 163/546 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEP112 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- CFAP92 | c.1895T>G p.L632R | Missense Mutation (SNP) | VAF 292/760 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFHR5 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 67/249 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CHD5 | c.2513C>T p.S838F | Missense Mutation (SNP) | VAF 246/819 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CHMP1B | c.106A>T p.I36F | Missense Mutation (SNP) | VAF 261/717 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- CILP | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 131/332 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, varscan2
- CLEC4D | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 114/323 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CNGB3 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 102/658 reads (16%) | called by muse, mutect2
- COG5 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COIL | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 260/643 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- COL27A1 | c.4152C>A p.P1384= | Splice Region (SNP) | VAF 260/726 reads (36%) | called by muse, mutect2, varscan2
- COL4A6 | c.2315_2324del p.H772Lfs*20 | Frame Shift Del (DEL) | VAF 175/270 reads (65%) | called by mutect2, pindel, varscan2
- COL8A2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 340/911 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRYBG3 | c.8825G>A p.G2942E | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- CTC1 | c.3302C>T p.P1101L | Missense Mutation (SNP) | VAF 264/776 reads (34%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CYP4A11 | c.819A>C p.Q273H | Missense Mutation (SNP) | VAF 107/369 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DCC | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 134/393 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- DEPDC4 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- DIRAS2 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 141/470 reads (30%) | called by muse, mutect2, varscan2
- DLEC1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 179/492 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DNAJC13 | c.4117C>A p.L1373I | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DPYS | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 107/474 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- DSCAM | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 145/407 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSG1 | c.2254G>A p.G752R | Missense Mutation (SNP) | VAF 192/574 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFNB2 | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EGFR | c.1312C>T p.L438F | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EHMT1 | c.1521T>G p.D507E | Missense Mutation (SNP) | VAF 220/641 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ELFN2 | c.1907C>T p.S636F | Missense Mutation (SNP) | VAF 313/938 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ELOA2 | c.1762C>T p.H588Y | Missense Mutation (SNP) | VAF 174/506 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENTR1 | c.1087C>T p.Q363* (on ENST00000357365 / NM_001039707.2; = p.Q340* on NM_006643.4) | Nonsense Mutation (SNP) | VAF 225/625 reads (36%) | called by muse, mutect2, varscan2
- ERVV-1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, varscan2
- EYS | c.4213C>T p.P1405S | Missense Mutation (SNP) | VAF 82/163 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- FAM193A | c.2561T>A p.F854Y | Missense Mutation (SNP) | VAF 164/448 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM221A | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 232/647 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXO16 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 110/355 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FGD5 | c.1807T>C p.S603P | Missense Mutation (SNP) | VAF 205/645 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- FGF9 | c.373T>A p.Y125N | Missense Mutation (SNP) | VAF 109/331 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FLG | c.5129G>A p.G1710E | Missense Mutation (SNP) | VAF 138/423 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FLT3 | c.855G>A p.W285* | Nonsense Mutation (SNP) | VAF 100/350 reads (29%) | called by muse, mutect2
- FRMPD1 | c.3574G>T p.G1192C | Missense Mutation (SNP) | VAF 168/528 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSIP2 | c.8168A>G p.K2723R | Missense Mutation (SNP) | VAF 125/431 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FSIP2 | c.16654G>A p.E5552K | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GALNT13 | c.203A>G p.K68R | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- GALNT13 | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.239); called by muse, varscan2
- GALNT13 | c.1245A>T p.E415D | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, varscan2
- GARRE1 | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 278/821 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GIPR | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 277/782 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLDN | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 181/548 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.007); called by muse, varscan2
- GPR171 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 83/268 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR55 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 212/606 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIK2 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 205/394 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- HCAR3 | c.1059G>A p.W353* | Nonsense Mutation (SNP) | VAF 214/601 reads (36%) | called by muse, mutect2, varscan2
- HCN4 | c.3419_3421dup p.R1140dup | In Frame Ins (INS) | VAF 288/858 reads (34%) | called by mutect2, pindel, varscan2
- HDAC9 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 96/304 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.092); called by muse, varscan2
- HECTD4 | c.13081C>T p.P4361S | Missense Mutation (SNP) | VAF 193/610 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- HECW2 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 87/278 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- HERC2 | c.1725G>A p.W575* | Nonsense Mutation (SNP) | VAF 309/856 reads (36%) | called by muse, mutect2, varscan2
- HEYL | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 314/902 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HOXC6 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 228/726 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HSPA14 | c.203A>G p.K68R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR3B | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 159/493 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IDO2 | c.452A>G p.N151S (on ENST00000389060; = p.N164S on NM_194294.2) | Missense Mutation (SNP) | VAF 98/332 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IFIH1 | c.929C>G p.P310R | Missense Mutation (SNP) | VAF 148/480 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- IGKC | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 198/813 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- IL9R | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 256/792 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- INPP5D | c.2698C>T p.P900S (on ENST00000445964 / NM_001017915.3; = p.P899S on NM_005541.5) | Missense Mutation (SNP) | VAF 148/414 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IQCA1 | c.407A>T p.K136I | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- IQCA1L | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 280/400 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- ITGA8 | c.2372G>A p.G791E | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- JPH1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 447/1760 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- KCNIP4 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 168/415 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KCTD2 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 286/905 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- KIAA1755 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 176/636 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1755 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 177/629 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- KIF1A | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 234/710 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIN | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KLF7 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 269/751 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP10-11 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 248/718 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- KRTAP4-9 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 246/776 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, varscan2
- LAMB2 | c.3206C>T p.P1069L | Missense Mutation (SNP) | VAF 276/790 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- LCOR | c.4492A>T p.K1498* | Nonsense Mutation (SNP) | VAF 32/519 reads (6%) | called by muse, mutect2
- LIPK | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LIPT1 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 95/225 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1B | c.1232G>A p.R411K | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC3B | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 111/327 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC4C | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 144/406 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LRRC9 | c.3148C>T p.H1050Y | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- LY86 | c.107G>A p.S36N | Missense Mutation (SNP) | VAF 181/726 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYPD8 | c.551A>C p.E184A | Missense Mutation (SNP) | VAF 187/592 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MAN1A1 | c.1011G>T p.W337C | Missense Mutation (SNP) | VAF 114/247 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARK1 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 219/710 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- MAT1A | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 150/238 reads (63%) | called by muse, mutect2, varscan2
- MATN1 | c.1259G>A p.R420K | Missense Mutation (SNP) | VAF 206/644 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MBD6 | c.2644A>T p.S882C | Missense Mutation (SNP) | VAF 371/1008 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MCRS1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 195/583 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- MEIKIN | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MFSD6L | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 202/600 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MIER2 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 327/957 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- MLNR | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 465/1347 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MLPH | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 213/572 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- MOGAT2 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 160/509 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- MROH5 | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 396/836 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- MTUS2 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 193/696 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- MTUS2 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 252/743 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC16 | c.24584C>T p.S8195L | Missense Mutation (SNP) | VAF 147/492 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- MYCBPAP | c.2165G>A p.R722K | Missense Mutation (SNP) | VAF 126/331 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MYH15 | c.3994G>A p.E1332K | Missense Mutation (SNP) | VAF 86/291 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- MYO1F | c.1657A>G p.K553E | Missense Mutation (SNP) | VAF 237/732 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- NBPF12 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- NELL1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 188/540 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- NEURL4 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 317/901 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NIBAN3 | c.1181T>A p.V394E | Missense Mutation (SNP) | VAF 313/879 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP2 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 317/970 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS2 | c.779G>A p.W260* | Nonsense Mutation (SNP) | VAF 244/730 reads (33%) | called by muse, mutect2, varscan2
- NOTCH1 | c.5890C>T p.P1964S | Missense Mutation (SNP) | VAF 350/966 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- NPIPA7 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | called by mutect2, varscan2
- NPIPA7 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NR4A1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 387/1029 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NRIP1 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 206/640 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRXN1 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 320/975 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NUP214 | c.3895T>G p.S1299A | Missense Mutation (SNP) | VAF 221/683 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NXPH1 | c.14G>A p.C5Y | Missense Mutation (SNP) | VAF 263/735 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR10H1 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 187/562 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- OR10S1 | c.388A>C p.T130P | Missense Mutation (SNP) | VAF 224/632 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- OR11A1 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 335/927 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- OR11H1 | c.282A>T p.K94N | Missense Mutation (SNP) | VAF 77/663 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- OR2G6 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 190/550 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- OR52E1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 152/448 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- OR5H8 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR8D4 | c.810G>T p.Q270H | Missense Mutation (SNP) | VAF 95/302 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- OR8J3 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OS9 | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 128/421 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OTOG | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 218/654 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAPOLA | c.292T>A p.F98I | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- PCDH11Y | c.560A>G p.N187S (on ENST00000400457 / NM_032973.2; = p.N176S on NM_032971.3) | Missense Mutation (SNP) | VAF 103/160 reads (64%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH15 | c.4628G>A p.G1543D (on ENST00000644397 / NM_001354429.2; = p.G1492D on NM_001142769.3) | Missense Mutation (SNP) | VAF 109/243 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH18 | c.2776G>A p.G926R | Missense Mutation (SNP) | VAF 120/382 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH7 | c.2039A>G p.E680G | Missense Mutation (SNP) | VAF 191/548 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCLO | c.13126G>A p.A4376T | Missense Mutation (SNP) | VAF 128/709 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE6C | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 194/364 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- PDK2 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 172/651 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PKHD1L1 | c.7219C>T p.P2407S | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- PLEKHA6 | c.648T>G p.C216W | Missense Mutation (SNP) | VAF 309/789 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PLEKHM1 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 189/563 reads (34%) | called by muse, mutect2, varscan2
- PLXNA3 | c.2648C>T p.S883F | Missense Mutation (SNP) | VAF 304/412 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- PON1 | c.636A>T p.E212D | Missense Mutation (SNP) | VAF 203/418 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PPP4R1 | c.1391C>T p.P464L (on ENST00000400556 / NM_001042388.3; = p.P447L on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 150/431 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAMEF6 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 126/718 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRDM8 | c.1136G>C p.G379A | Missense Mutation (SNP) | VAF 437/1266 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PRDX1 | c.346T>G p.Y116D | Missense Mutation (SNP) | VAF 42/650 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRQ | c.6350G>A p.G2117E (on ENST00000616559; = p.G2084E on NM_001145026.2) | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2
- PTPRQ | c.6352G>A p.D2118N (on ENST00000616559; = p.D2085N on NM_001145026.2) | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBBP8NL | c.1793A>G p.E598G | Missense Mutation (SNP) | VAF 206/624 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.559); called by mutect2, varscan2
- RGPD2 | c.4030G>A p.E1344K | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RGS12 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 283/800 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIMBP2 | c.2987G>A p.G996E | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNASE10 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 208/593 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- RNF128 | c.523A>C p.K175Q (on ENST00000255499 / NM_194463.2; = p.K149Q on NM_024539.3) | Missense Mutation (SNP) | VAF 48/72 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- RP1 | c.3383C>T p.S1128L | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RP1L1 | c.2717G>A p.G906E | Missense Mutation (SNP) | VAF 408/1032 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- RYR1 | c.6229G>A p.E2077K | Missense Mutation (SNP) | VAF 165/518 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RYR3 | c.7823C>T p.S2608F (on ENST00000389232; = p.S2609F on NM_001036.6) | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- RYR3 | c.9224C>T p.P3075L (on ENST00000389232; = p.P3076L on NM_001036.6) | Missense Mutation (SNP) | VAF 181/518 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SACS | c.10984G>A p.E3662K | Missense Mutation (SNP) | VAF 123/413 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SAMD9 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 88/150 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, varscan2
- SAMSN1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- SCAF1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 116/322 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- SETBP1 | c.3943C>T p.Q1315* | Nonsense Mutation (SNP) | VAF 135/487 reads (28%) | called by muse, mutect2, varscan2
- SH3TC2 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 165/292 reads (57%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.3782G>A p.G1261E | Missense Mutation (SNP) | VAF 138/439 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- SLC12A5 | c.1220C>T p.P407L (on ENST00000454036 / NM_001134771.2; = p.P384L on NM_020708.5) | Missense Mutation (SNP) | VAF 169/576 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC13A1 | c.1532A>G p.N511S | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SLC36A1 | c.692G>T p.S231I | Missense Mutation (SNP) | VAF 80/153 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC6A1 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 207/567 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC7A6OS | c.550G>C p.G184R | Missense Mutation (SNP) | VAF 181/548 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLIT2 | c.1523A>G p.E508G | Missense Mutation (SNP) | VAF 186/536 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- SMPD3 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 170/538 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- SMTNL2 | c.632C>G p.T211S (on ENST00000389313 / NM_001114974.2; = p.T67S on NM_198501.3) | Missense Mutation (SNP) | VAF 291/801 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SNX19 | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 152/459 reads (33%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- SNX6 | c.599T>A p.F200Y (on ENST00000652385; = p.F72Y on NM_021249.5) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- SORCS2 | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 169/457 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOX10 | c.512A>G p.Y171C | Missense Mutation (SNP) | VAF 345/1001 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPON1 | c.2261-1G>A p.X754_splice | Splice Site (SNP) | VAF 124/352 reads (35%) | called by muse, mutect2, varscan2
- SPTAN1 | c.3602C>T p.T1201I | Missense Mutation (SNP) | VAF 142/481 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SRCAP | c.4265C>T p.P1422L | Missense Mutation (SNP) | VAF 223/701 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- SSC5D | c.3712A>G p.T1238A | Missense Mutation (SNP) | VAF 249/899 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYT6 | c.302C>T p.P101L (on ENST00000610222 / NM_001366225.1; = p.P16L on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 258/788 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYTL4 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 110/169 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- SYVN1 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 182/528 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- TECPR2 | c.2089C>T p.L697F | Missense Mutation (SNP) | VAF 191/644 reads (30%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TECRL | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- TONSL | c.3751G>C p.A1251P | Missense Mutation (SNP) | VAF 165/699 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- TRAPPC10 | c.1888C>T p.H630Y | Missense Mutation (SNP) | VAF 206/610 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TRPS1 | c.172G>A p.E58K (on ENST00000220888 / NM_001330599.2; = p.E71K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/512 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- TTN | c.70136G>A p.R23379K (on ENST00000591111; = p.R15955K on NM_003319.4) | Missense Mutation (SNP) | VAF 141/402 reads (35%) | PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TUBGCP3 | c.1116T>G p.Y372* | Nonsense Mutation (SNP) | VAF 288/832 reads (35%) | called by muse, mutect2, varscan2
- UBR4 | c.2109T>G p.D703E | Missense Mutation (SNP) | VAF 111/272 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- UCP1 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 202/547 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT2A3 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- UNC13C | c.3176C>T p.S1059F | Missense Mutation (SNP) | VAF 64/302 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- UPF2 | c.3075A>C p.E1025D | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- UTY | c.1246T>C p.Y416H | Missense Mutation (SNP) | VAF 57/82 reads (70%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- VGLL3 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- VPS13A | c.1669T>G p.S557A | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- XIRP2 | c.548C>T p.P183L (on ENST00000628543; = p.P358L on NM_152381.6) | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC3H11B | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 79/357 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF134 | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 122/336 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF253 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF423 | c.2018C>T p.P673L (on ENST00000563137 / NM_001379286.1; = p.P665L on NM_015069.4) | Missense Mutation (SNP) | VAF 245/647 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- ZNF536 | c.740G>A p.S247N | Missense Mutation (SNP) | VAF 377/1079 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF536 | c.2312G>A p.R771K | Missense Mutation (SNP) | VAF 141/389 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF547 | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 171/544 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZPBP2 | c.285G>A p.M95I (on ENST00000348931 / NM_199321.3; = p.M73I on NM_198844.3) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABCC10 | c.1722C>T p.F574= (on ENST00000372530 / NM_001198934.2; = p.F531= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 157/530 reads (30%) | called by muse, mutect2, varscan2
- ABCC8 | c.1581G>A p.R527= | Silent (SNP) | VAF 228/652 reads (35%) | catalogued as rs750360514, CD016052, COSV56856861; called by muse, mutect2, varscan2
- ADCY10 | c.432G>A p.K144= | Silent (SNP) | VAF 112/308 reads (36%) | catalogued as COSV100896878; called by muse, mutect2, varscan2
- AKR1C1 | c.696C>T p.S232= | Silent (SNP) | VAF 192/813 reads (24%) | called by muse, mutect2, varscan2
- ALKBH4 | c.618C>T p.A206= | Silent (SNP) | VAF 403/1371 reads (29%) | catalogued as rs1166582994; called by muse, mutect2, varscan2
- ARHGEF7 | c.1179C>T p.S393= (on ENST00000375741 / NM_001113511.2; = p.S215= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 188/586 reads (32%) | catalogued as COSV54538507; called by muse, mutect2, varscan2
- ASXL3 | c.1329G>A p.L443= | Silent (SNP) | VAF 90/264 reads (34%) | called by muse, mutect2, varscan2
- ATP2B2 | c.861C>T p.T287= | Silent (SNP) | VAF 169/528 reads (32%) | catalogued as rs780890460, COSV59506843; called by muse, mutect2, varscan2
- ATP2B2 | c.330C>T p.I110= | Silent (SNP) | VAF 305/893 reads (34%) | called by muse, mutect2, varscan2
- B4GALNT2 | c.993C>T p.L331= | Silent (SNP) | VAF 126/387 reads (33%) | catalogued as rs745364695, COSV100302348; called by muse, mutect2, varscan2
- BCL2L12 | c.51C>T p.F17= | Silent (SNP) | VAF 186/525 reads (35%) | catalogued as rs267605591, COSV55862539; called by muse, mutect2, varscan2
- BCL3 | c.387C>T p.T129= | Silent (SNP) | VAF 186/572 reads (33%) | called by muse, mutect2, varscan2
- BDP1 | c.3540T>C p.G1180= | Silent (SNP) | VAF 145/438 reads (33%) | called by muse, mutect2
- BRCA2 | c.999C>T p.F333= | Silent (SNP) | VAF 54/164 reads (33%) | called by muse, mutect2, varscan2
- BRCA2 | c.1752A>G p.K584= | Silent (SNP) | VAF 64/208 reads (31%) | called by muse, mutect2, varscan2
- BTNL3 | c.984G>A p.K328= | Silent (SNP) | VAF 167/486 reads (34%) | catalogued as COSV61565448, COSV61566204; called by muse, mutect2, varscan2
- C10orf71 | c.2568G>A p.T856= | Silent (SNP) | VAF 198/373 reads (53%) | catalogued as rs746121240; called by muse, mutect2, varscan2
- C2orf76 | c.39C>T p.I13= | Silent (SNP) | VAF 114/390 reads (29%) | catalogued as COSV58348213; called by muse, mutect2, varscan2
- C3 | c.1896G>A p.G632= | Silent (SNP) | VAF 184/532 reads (35%) | catalogued as COSV55581411; called by muse, mutect2, varscan2
- CA10 | c.84C>T p.I28= | Silent (SNP) | VAF 77/267 reads (29%) | catalogued as COSV53351691; called by muse, mutect2, varscan2
- CA2 | c.777C>T p.F259= | Silent (SNP) | VAF 223/406 reads (55%) | called by muse, mutect2, varscan2
- CACNB2 | c.273C>T p.D91= (on ENST00000324631 / NM_201596.3; = p.D36= on NM_000724.4) | Silent (SNP) | VAF 151/447 reads (34%) | catalogued as rs147650257; called by muse, mutect2, varscan2
- CAMSAP3 | c.2298C>T p.T766= | Silent (SNP) | VAF 451/1254 reads (36%) | catalogued as rs1384336027; called by muse, mutect2, varscan2
- CAPN9 | c.393C>T p.F131= | Silent (SNP) | VAF 129/401 reads (32%) | catalogued as COSV55233720; called by muse, mutect2, varscan2
- CARD11 | c.210C>T p.I70= | Silent (SNP) | VAF 122/408 reads (30%) | called by muse, mutect2, varscan2
- CCDC159 | c.571C>T p.L191= | Silent (SNP) | VAF 145/390 reads (37%) | called by muse, mutect2, varscan2
- CCR8 | c.624G>A p.L208= | Silent (SNP) | VAF 139/399 reads (35%) | called by muse, mutect2, varscan2
- CDH5 | c.345G>A p.E115= | Silent (SNP) | VAF 288/846 reads (34%) | catalogued as rs1211000132; called by muse, mutect2
- CDK6 | c.492C>T p.F164= | Silent (SNP) | VAF 491/933 reads (53%) | catalogued as rs774750394, COSV56005149; called by muse, mutect2, varscan2
- CEACAM19 | c.297C>T p.I99= | Silent (SNP) | VAF 188/527 reads (36%) | catalogued as rs764374932; called by muse, mutect2, varscan2
- CFAP126 | c.384G>A p.K128= | Silent (SNP) | VAF 139/457 reads (30%) | called by muse, mutect2, varscan2
- CFHR1 | c.552G>A p.G184= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as rs750090708; called by muse, mutect2, varscan2
- CHRM2 | c.501G>A p.G167= | Silent (SNP) | VAF 401/795 reads (50%) | called by muse, mutect2, varscan2
- CHST10 | c.765G>A p.Q255= | Silent (SNP) | VAF 212/638 reads (33%) | called by muse, mutect2, varscan2
- CILP | c.861C>T p.L287= | Silent (SNP) | VAF 167/534 reads (31%) | catalogued as COSV56025958; called by muse, mutect2, varscan2
- CLCN1 | c.327G>A p.V109= | Silent (SNP) | VAF 90/433 reads (21%) | called by muse, mutect2, varscan2
- CLEC4M | c.924T>G p.T308= | Silent (SNP) | VAF 101/307 reads (33%) | called by muse, mutect2, varscan2
- CLIC6 | c.84C>T p.P28= | Silent (SNP) | VAF 412/1140 reads (36%) | catalogued as rs1192267571; called by muse, mutect2, varscan2
- CNTNAP5 | c.1083C>T p.S361= | Silent (SNP) | VAF 157/435 reads (36%) | catalogued as rs778725471; called by muse, mutect2, varscan2
- COL26A1 | c.222G>A p.T74= | Silent (SNP) | VAF 476/928 reads (51%) | catalogued as rs373555150; called by muse, mutect2, varscan2
- COL4A4 | c.1980T>C p.G660= | Silent (SNP) | VAF 134/378 reads (35%) | called by muse, varscan2
- CORO1C | c.1209G>A p.K403= | Silent (SNP) | VAF 178/529 reads (34%) | catalogued as rs767688304; called by muse, mutect2, varscan2
- CPLX1 | c.375C>T p.P125= | Silent (SNP) | VAF 244/620 reads (39%) | catalogued as rs770257151; called by muse, mutect2, varscan2
- CTC1 | c.3456C>T p.L1152= | Silent (SNP) | VAF 155/532 reads (29%) | called by muse, mutect2, varscan2
- CYP1A2 | c.678C>T p.F226= | Silent (SNP) | VAF 191/595 reads (32%) | catalogued as COSV59659773; called by muse, mutect2, varscan2
- CYP21A2 | c.171G>C p.G57= | Silent (SNP) | VAF 302/891 reads (34%) | called by muse, varscan2
- CYP2C18 | c.940C>T p.L314= | Silent (SNP) | VAF 114/228 reads (50%) | called by muse, mutect2, varscan2
- DMRT3 | c.1272C>T p.V424= | Silent (SNP) | VAF 214/548 reads (39%) | called by muse, mutect2, varscan2
- DMRTC2 | c.453C>T p.S151= | Silent (SNP) | VAF 144/423 reads (34%) | called by muse, varscan2
- DNAH5 | c.4812C>T p.F1604= | Silent (SNP) | VAF 93/298 reads (31%) | catalogued as COSV54248062, COSV54253190; called by muse, mutect2, varscan2
- DNAH9 | c.10527G>A p.L3509= | Silent (SNP) | VAF 95/327 reads (29%) | called by muse, mutect2, varscan2
- DNMT3B | c.504C>T p.I168= | Silent (SNP) | VAF 259/805 reads (32%) | catalogued as rs781020047; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOCK2 | c.909C>G p.G303= | Silent (SNP) | VAF 128/410 reads (31%) | called by muse, mutect2, varscan2
- DSCAM | c.4689C>T p.F1563= | Silent (SNP) | VAF 146/424 reads (34%) | catalogued as rs201376842, COSV68023011; called by muse, mutect2, varscan2
- DSG1 | c.2691G>A p.R897= | Silent (SNP) | VAF 178/544 reads (33%) | catalogued as COSV99935661; called by muse, mutect2, varscan2
- E2F8 | c.1419C>T p.A473= | Silent (SNP) | VAF 204/634 reads (32%) | called by muse, mutect2, varscan2
- EIF2B2 | c.357C>T p.N119= | Silent (SNP) | VAF 221/645 reads (34%) | called by muse, mutect2, varscan2
- ENDOD1 | c.1293C>T p.V431= | Silent (SNP) | VAF 173/582 reads (30%) | called by muse, mutect2, varscan2
- EPHA2 | c.915C>T p.T305= | Silent (SNP) | VAF 283/811 reads (35%) | called by muse, mutect2, varscan2
- EPN2 | c.615C>T p.C205= | Silent (SNP) | VAF 282/793 reads (36%) | called by muse, varscan2
- EPO | c.441C>T p.S147= | Silent (SNP) | VAF 292/614 reads (48%) | catalogued as COSV53161911; called by muse, mutect2, varscan2
- EVPL | c.2310C>T p.P770= | Silent (SNP) | VAF 362/991 reads (37%) | called by muse, mutect2, varscan2
- FBN3 | c.7947C>T p.V2649= | Silent (SNP) | VAF 109/361 reads (30%) | called by muse, mutect2, varscan2
- FGF23 | c.324C>T p.F108= | Silent (SNP) | VAF 116/387 reads (30%) | catalogued as rs201114020, COSV52975615; called by muse, mutect2, varscan2
- FIGNL2 | c.321C>T p.P107= | Silent (SNP) | VAF 336/921 reads (36%) | called by muse, mutect2, varscan2
- FMO3 | c.273C>T p.I91= | Silent (SNP) | VAF 76/254 reads (30%) | catalogued as COSV100882568, COSV63007970; called by muse, mutect2, varscan2
- FMO3 | c.1122C>T p.S374= | Silent (SNP) | VAF 159/471 reads (34%) | catalogued as rs867914992, COSV63006550; called by muse, mutect2, varscan2
- FSIP2 | c.16434G>A p.K5478= | Silent (SNP) | VAF 51/153 reads (33%) | called by muse, mutect2, varscan2
- FSIP2 | c.19122A>G p.S6374= | Silent (SNP) | VAF 46/136 reads (34%) | called by muse, mutect2, varscan2
- GAREM1 | c.759C>T p.S253= | Silent (SNP) | VAF 213/679 reads (31%) | called by muse, mutect2, varscan2
- GAS7 | c.1266C>T p.H422= (on ENST00000432992 / NM_201433.2; = p.H282= on NM_003644.3) | Silent (SNP) | VAF 196/620 reads (32%) | catalogued as rs1179969708; called by muse, mutect2, varscan2
- GNAO1 | c.411C>T p.I137= | Silent (SNP) | VAF 240/650 reads (37%) | catalogued as COSV52610682; called by muse, mutect2, varscan2
- GPHB5 | c.96C>T p.T32= | Silent (SNP) | VAF 216/659 reads (33%) | called by muse, mutect2, varscan2
- GPR4 | c.969G>A p.L323= | Silent (SNP) | VAF 342/964 reads (35%) | called by muse, mutect2, varscan2
- H1-2 | c.336C>T p.A112= | Silent (SNP) | VAF 226/634 reads (36%) | catalogued as rs142935980; called by muse, varscan2
- H1-3 | c.384G>A p.K128= | Silent (SNP) | VAF 312/884 reads (35%) | catalogued as rs1287446183; called by muse, mutect2, varscan2
- HAO2 | c.198G>A p.G66= | Silent (SNP) | VAF 199/656 reads (30%) | called by muse, mutect2, varscan2
- HCN1 | c.558C>T p.F186= | Silent (SNP) | VAF 58/167 reads (35%) | catalogued as rs1060500097, COSV57495408; called by muse, mutect2, varscan2
- HECW2 | c.1287C>T p.S429= | Silent (SNP) | VAF 154/466 reads (33%) | catalogued as COSV53662765; called by muse, mutect2, varscan2
- HK3 | c.1638G>A p.T546= | Silent (SNP) | VAF 246/695 reads (35%) | catalogued as rs758157580, COSV52844179; called by muse, mutect2, varscan2
- HSF4 | c.387C>T p.G129= | Silent (SNP) | VAF 285/815 reads (35%) | called by muse, mutect2, varscan2
- HYDIN | c.4626C>T p.D1542= | Silent (SNP) | VAF 90/275 reads (33%) | catalogued as rs552617421; called by muse, mutect2, varscan2
- IGHV3-48 | c.183G>A p.G61= | Silent (SNP) | VAF 34/260 reads (13%) | called by muse, mutect2
- IGLV1-47 | c.138C>T p.S46= | Silent (SNP) | VAF 173/478 reads (36%) | catalogued as rs1206577030; called by muse, mutect2, varscan2
- IGLV3-19 | c.225G>A p.G75= | Silent (SNP) | VAF 149/465 reads (32%) | called by muse, mutect2, varscan2
- IGSF21 | c.729G>A p.T243= | Silent (SNP) | VAF 322/973 reads (33%) | catalogued as rs371864848, COSV52137711; called by muse, mutect2, varscan2
- IKZF4 | c.711C>T p.H237= | Silent (SNP) | VAF 125/412 reads (30%) | called by muse, mutect2, varscan2
- IRF6 | c.1200G>A p.R400= | Silent (SNP) | VAF 122/380 reads (32%) | catalogued as rs780377253, COSV54214666; called by muse, mutect2, varscan2
- ISM2 | c.426G>A p.E142= | Silent (SNP) | VAF 101/295 reads (34%) | catalogued as rs1490667085; called by muse, mutect2, varscan2
- ITGA2B | c.2514C>T p.S838= | Silent (SNP) | VAF 205/596 reads (34%) | called by muse, mutect2, varscan2
- ITGA9 | c.2835G>A p.V945= | Silent (SNP) | VAF 167/522 reads (32%) | called by muse, mutect2, varscan2
- KCNB1 | c.1335C>T p.I445= | Silent (SNP) | VAF 133/433 reads (31%) | catalogued as rs368667514, COSV65569351; called by muse, mutect2, varscan2
- KCNH5 | c.2013G>A p.R671= | Silent (SNP) | VAF 74/230 reads (32%) | catalogued as COSV59770839; called by muse, mutect2, varscan2
- KCTD2 | c.84C>T p.V28= | Silent (SNP) | VAF 292/903 reads (32%) | catalogued as rs958143696; called by muse, mutect2, varscan2
- KIF1A | c.4491C>T p.L1497= (on ENST00000320389 / NM_001379639.1; = p.L1489= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 136/432 reads (31%) | catalogued as rs779877210; called by muse, mutect2, varscan2
- KIF21B | c.2607C>T p.I869= | Silent (SNP) | VAF 281/781 reads (36%) | catalogued as rs746319254, COSV59751690; called by muse, mutect2, varscan2
- KIRREL3 | c.336G>A p.L112= | Silent (SNP) | VAF 256/715 reads (36%) | called by muse, mutect2, varscan2
- KLHDC7A | c.6C>T p.F2= | Silent (SNP) | VAF 114/347 reads (33%) | catalogued as rs1227974701; called by muse, mutect2, varscan2
- KLHL28 | c.1590C>T p.V530= | Silent (SNP) | VAF 94/309 reads (30%) | catalogued as rs759182642; called by muse, varscan2
- KLK13 | c.693C>T p.I231= | Silent (SNP) | VAF 161/479 reads (34%) | catalogued as rs765329818; called by muse, mutect2, varscan2
- KRT76 | c.516C>T p.I172= | Silent (SNP) | VAF 183/586 reads (31%) | catalogued as rs146014128, COSV60121833; called by muse, mutect2, varscan2
- KRT82 | c.1245C>T p.I415= | Silent (SNP) | VAF 160/547 reads (29%) | catalogued as rs149421540; called by muse, mutect2, varscan2
- KRTAP1-5 | c.48C>T p.I16= | Silent (SNP) | VAF 132/364 reads (36%) | called by muse, mutect2, varscan2
- KRTAP5-1 | c.339G>A p.G113= | Silent (SNP) | VAF 177/331 reads (53%) | called by mutect2, varscan2
- LAMP5 | c.99G>A p.V33= | Silent (SNP) | VAF 149/455 reads (33%) | called by muse, mutect2, varscan2
- LDB2 | c.771G>A p.R257= | Silent (SNP) | VAF 218/589 reads (37%) | catalogued as rs539193176; called by muse, mutect2, varscan2
- LEMD1 | c.543T>C p.G181= | Silent (SNP) | VAF 116/335 reads (35%) | catalogued as COSV100903452; called by muse, mutect2, varscan2
- LRFN2 | c.141C>T p.P47= | Silent (SNP) | VAF 265/732 reads (36%) | called by muse, mutect2, varscan2
- MAGEA6 | c.750C>T p.F250= | Silent (SNP) | VAF 221/302 reads (73%) | catalogued as rs782585932, COSV61448617, COSV61449289; called by muse, mutect2, varscan2
- MALRD1 | c.978C>T p.F326= | Silent (SNP) | VAF 73/265 reads (28%) | called by muse, mutect2, varscan2
- MALRD1 | c.1371G>A p.Q457= | Silent (SNP) | VAF 149/465 reads (32%) | called by muse, mutect2, varscan2
- MCF2L2 | c.1389C>T p.I463= | Silent (SNP) | VAF 164/503 reads (33%) | catalogued as rs923350801; called by muse, mutect2, varscan2
- MED16 | c.2337C>T p.I779= | Silent (SNP) | VAF 302/871 reads (35%) | catalogued as rs139834365; called by muse, mutect2, varscan2
- MEIS3 | c.975C>T p.I325= (on ENST00000558555 / NM_001346148.1; = p.I371= on NM_020160.3) | Silent (SNP) | VAF 207/597 reads (35%) | catalogued as rs1223053853, COSV58983224; called by muse, mutect2, varscan2
- MEP1A | c.1977C>T p.G659= | Silent (SNP) | VAF 242/733 reads (33%) | catalogued as COSV57920679; called by muse, mutect2, varscan2
- MGAM | c.5487C>T p.P1829= | Silent (SNP) | VAF 290/630 reads (46%) | catalogued as COSV72074007; called by muse, mutect2, varscan2
- MROH2B | c.3345G>A p.G1115= | Silent (SNP) | VAF 127/418 reads (30%) | catalogued as rs549275471, COSV68182646; called by muse, mutect2, varscan2
- MTUS2 | c.936G>A p.L312= | Silent (SNP) | VAF 246/728 reads (34%) | called by muse, varscan2
- MUC4 | c.15942C>T p.P5314= (on ENST00000463781 / NM_018406.7; = p.P1078= on NM_004532.6) | Silent (SNP) | VAF 394/2660 reads (15%) | catalogued as rs1367696878, COSV100204530, COSV57797019; called by muse, mutect2
- MXRA5 | c.2331G>A p.Q777= | Silent (SNP) | VAF 170/245 reads (69%) | catalogued as COSV54243153; called by muse, mutect2, varscan2
- MYO15A | c.624C>T p.F208= | Silent (SNP) | VAF 322/817 reads (39%) | catalogued as COSV52751465; called by muse, mutect2, varscan2
- MYO5C | c.340T>C p.L114= | Silent (SNP) | VAF 168/497 reads (34%) | called by muse, mutect2, varscan2
- MYOCD | c.387G>A p.V129= | Silent (SNP) | VAF 130/377 reads (34%) | catalogued as COSV58513519; called by muse, mutect2, varscan2
- MYOCD | c.2382C>T p.I794= | Silent (SNP) | VAF 187/569 reads (33%) | catalogued as COSV100591551, COSV58509984; called by muse, mutect2, varscan2
- NCR3LG1 | c.702C>T p.S234= | Silent (SNP) | VAF 140/502 reads (28%) | called by muse, mutect2, varscan2
- NLGN4Y | c.2100G>A p.K700= | Silent (SNP) | VAF 229/325 reads (70%) | called by muse, mutect2, varscan2
- NLRP2 | c.1737G>A p.P579= | Silent (SNP) | VAF 214/721 reads (30%) | catalogued as rs530937104; called by muse, mutect2, varscan2
- NLRP2 | c.1887C>T p.S629= | Silent (SNP) | VAF 242/786 reads (31%) | called by muse, mutect2, varscan2
- NPIPB5 | c.1098C>T p.L366= | Silent (SNP) | VAF 119/680 reads (18%) | called by muse, mutect2, varscan2
- NPTX2 | c.864C>T p.P288= | Silent (SNP) | VAF 185/742 reads (25%) | catalogued as rs1464132127, COSV55718458; called by muse, mutect2, varscan2
- NTRK3 | c.2481G>A p.L827= (on ENST00000360948 / NM_001012338.2; = p.L813= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 281/727 reads (39%) | catalogued as COSV62308482, COSV62312574, COSV62316524; called by muse, mutect2, varscan2
- NXPH3 | c.183C>T p.A61= | Silent (SNP) | VAF 393/1070 reads (37%) | catalogued as rs778437274; called by muse, mutect2, varscan2
- OGDH | c.2124C>T p.P708= | Silent (SNP) | VAF 189/546 reads (35%) | called by muse, mutect2, varscan2
- OR10G6 | c.402C>T p.F134= | Silent (SNP) | VAF 148/475 reads (31%) | catalogued as rs1332757912; called by muse, mutect2, varscan2
- OR1C1 | c.504C>T p.F168= | Silent (SNP) | VAF 193/545 reads (35%) | catalogued as COSV101376256; called by muse, mutect2, varscan2
- OR1G1 | c.738C>T p.S246= | Silent (SNP) | VAF 158/468 reads (34%) | catalogued as rs762912158, COSV61030515; called by muse, mutect2, varscan2
- OR1L3 | c.462C>T p.F154= | Silent (SNP) | VAF 149/462 reads (32%) | catalogued as rs750460042; called by muse, mutect2, varscan2
- OR2AG2 | c.618C>T p.F206= | Silent (SNP) | VAF 187/539 reads (35%) | called by muse, mutect2, varscan2
- OR2G6 | c.237A>C p.P79= | Silent (SNP) | VAF 263/733 reads (36%) | called by muse, mutect2, varscan2
- OR2L5 | c.804A>T p.T268= | Silent (SNP) | VAF 92/285 reads (32%) | called by muse, mutect2, varscan2
- OR2T8 | c.825C>T p.F275= | Silent (SNP) | VAF 30/504 reads (6%) | called by muse, mutect2
- OR51D1 | c.18C>T p.L6= | Silent (SNP) | VAF 142/383 reads (37%) | called by muse, mutect2, varscan2
- OR51I1 | c.423C>T p.N141= | Silent (SNP) | VAF 170/570 reads (30%) | called by muse, mutect2, varscan2
- OR5B12 | c.675G>A p.K225= | Silent (SNP) | VAF 98/328 reads (30%) | catalogued as COSV56906534; called by muse, mutect2, varscan2
- OR5BS1P | c.855C>T p.P285= | Silent (SNP) | VAF 193/585 reads (33%) | called by muse, mutect2, varscan2
- OR5D18 | c.939C>T p.Y313= | Silent (SNP) | VAF 58/171 reads (34%) | called by muse, mutect2, varscan2
- OR8H2 | c.765G>A p.L255= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs1364453583, COSV57943487; called by muse, mutect2, varscan2
- OTOF | c.5982C>T p.I1994= (on ENST00000272371 / NM_194248.3; = p.I1227= on NM_004802.4) | Silent (SNP) | VAF 208/815 reads (26%) | catalogued as COSV55502185; called by muse, mutect2, varscan2
- P2RY6 | c.72C>T p.F24= | Silent (SNP) | VAF 285/806 reads (35%) | called by muse, mutect2, varscan2
- PAPPA2 | c.1725C>T p.S575= | Silent (SNP) | VAF 246/702 reads (35%) | catalogued as rs959030331, COSV62786896; called by muse, mutect2, varscan2
- PAX7 | c.114C>T p.V38= | Silent (SNP) | VAF 245/789 reads (31%) | called by muse, mutect2
- PCDHA11 | c.685T>C p.L229= | Silent (SNP) | VAF 142/240 reads (59%) | catalogued as rs782425741; called by muse, mutect2, varscan2
- PCDHA13 | c.270C>T p.I90= | Silent (SNP) | VAF 315/550 reads (57%) | catalogued as rs782086663, COSV56477733; called by muse, varscan2
- PCDHA9 | c.1125C>T p.I375= | Silent (SNP) | VAF 234/445 reads (53%) | catalogued as COSV65332115; called by muse, mutect2, varscan2
- PCDHGA10 | c.1755C>T p.S585= | Silent (SNP) | VAF 339/636 reads (53%) | catalogued as rs561548499; called by muse, mutect2, varscan2
- PCF11 | c.3411T>C p.D1137= | Silent (SNP) | VAF 100/293 reads (34%) | called by muse, mutect2, varscan2
- PCSK1 | c.1824G>A p.T608= | Silent (SNP) | VAF 131/430 reads (30%) | catalogued as rs753294559; called by muse, mutect2, varscan2
- PDK2 | c.468C>T p.D156= | Silent (SNP) | VAF 172/660 reads (26%) | called by muse, mutect2, varscan2
- PER3 | c.1845C>T p.I615= | Silent (SNP) | VAF 220/650 reads (34%) | called by muse, mutect2, varscan2
- PHF21B | c.1395G>A p.K465= | Silent (SNP) | VAF 199/617 reads (32%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.3687G>A p.R1229= | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.7671G>A p.V2557= | Silent (SNP) | VAF 340/681 reads (50%) | called by muse, mutect2, varscan2
- PLA2G4D | c.2208C>T p.S736= | Silent (SNP) | VAF 206/634 reads (32%) | called by muse, mutect2, varscan2
- PLIN1 | c.1500C>T p.F500= | Silent (SNP) | VAF 396/1055 reads (38%) | catalogued as rs1376154735; called by muse, varscan2
- POSTN | c.372G>A p.E124= | Silent (SNP) | VAF 197/621 reads (32%) | catalogued as rs369828402, COSV65712010; called by muse, mutect2, varscan2
- PPP4R3C | c.1011C>T p.F337= | Silent (SNP) | VAF 39/70 reads (56%) | called by muse, mutect2, varscan2
- PRAMEF4 | c.1161C>T p.F387= | Silent (SNP) | VAF 128/225 reads (57%) | catalogued as COSV52441102; called by muse, mutect2, varscan2
- PROZ | c.186C>T p.I62= | Silent (SNP) | VAF 124/421 reads (29%) | catalogued as COSV61439869; called by muse, mutect2, varscan2
- PRR14 | c.651A>G p.P217= | Silent (SNP) | VAF 196/552 reads (36%) | called by muse, mutect2, varscan2
- PXDN | c.2586C>T p.I862= | Silent (SNP) | VAF 234/538 reads (43%) | catalogued as rs1189597990, COSV53229472; called by mutect2, varscan2
- PXDN | c.1278C>T p.F426= | Silent (SNP) | VAF 126/340 reads (37%) | catalogued as rs753957482; called by muse, mutect2, varscan2
- RAD54L | c.1089G>A p.K363= | Silent (SNP) | VAF 187/586 reads (32%) | called by muse, mutect2, varscan2
- RAG1 | c.99C>T p.F33= | Silent (SNP) | VAF 126/415 reads (30%) | catalogued as COSV55027376; called by muse, mutect2, varscan2
- RANBP17 | c.675C>T p.C225= | Silent (SNP) | VAF 86/266 reads (32%) | catalogued as COSV66652761; called by muse, mutect2, varscan2
- RANBP9 | c.1686C>T p.D562= | Silent (SNP) | VAF 51/163 reads (31%) | catalogued as rs1166044895; called by muse, mutect2, varscan2
- RBBP8NL | c.1794G>A p.E598= | Silent (SNP) | VAF 205/626 reads (33%) | catalogued as rs1188259914; called by mutect2, varscan2
- RELN | c.5802G>A p.K1934= | Silent (SNP) | VAF 38/146 reads (26%) | catalogued as COSV100634488; called by muse, mutect2, varscan2
- RGL1 | c.1314C>T p.I438= (on ENST00000360851 / NM_001297672.2; = p.I473= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 116/354 reads (33%) | catalogued as rs770302492; called by muse, mutect2, varscan2
- RIMBP2 | c.2544C>T p.L848= | Silent (SNP) | VAF 204/581 reads (35%) | catalogued as COSV99898431; called by muse, mutect2, varscan2
- ROR1 | c.297C>T p.V99= | Silent (SNP) | VAF 229/664 reads (34%) | catalogued as rs1464485331; called by muse, mutect2, varscan2
- RP1 | c.3111C>T p.L1037= | Silent (SNP) | VAF 293/579 reads (51%) | called by muse, mutect2, varscan2
- RREB1 | c.126C>T p.S42= | Silent (SNP) | VAF 190/731 reads (26%) | called by muse, mutect2, varscan2
- RYR3 | c.6831C>T p.I2277= (on ENST00000389232; = p.I2278= on NM_001036.6) | Silent (SNP) | VAF 122/490 reads (25%) | catalogued as rs772909257; called by muse, mutect2
- SALL3 | c.2334C>T p.A778= | Silent (SNP) | VAF 446/1244 reads (36%) | called by muse, varscan2
- SALL3 | c.3273G>A p.Q1091= | Silent (SNP) | VAF 558/1526 reads (37%) | called by muse, mutect2, varscan2
- SCAF1 | c.3486C>T p.S1162= | Silent (SNP) | VAF 319/893 reads (36%) | catalogued as rs1460100116; called by muse, mutect2, varscan2
- SDHC | c.438C>T p.P146= | Silent (SNP) | VAF 138/537 reads (26%) | catalogued as rs1418513098, COSV100713625; called by muse, mutect2, varscan2
- SERBP1 | c.54C>T p.D18= | Silent (SNP) | VAF 231/620 reads (37%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.2349C>T p.F783= | Silent (SNP) | VAF 171/504 reads (34%) | catalogued as COSV62168385; called by muse, mutect2, varscan2
- SLC12A5 | c.336G>A p.K112= (on ENST00000454036 / NM_001134771.2; = p.K89= on NM_020708.5) | Silent (SNP) | VAF 116/333 reads (35%) | catalogued as rs762781492; called by muse, mutect2, varscan2
- SLC1A3 | c.1599G>A p.E533= | Silent (SNP) | VAF 62/241 reads (26%) | called by muse, mutect2, varscan2
- SLC22A15 | c.675G>A p.R225= | Silent (SNP) | VAF 132/363 reads (36%) | catalogued as rs1176032648; called by muse, mutect2, varscan2
- SLC26A8 | c.2274T>A p.I758= | Silent (SNP) | VAF 96/312 reads (31%) | called by muse, mutect2, varscan2
- SLC2A9 | c.1401C>T p.L467= | Silent (SNP) | VAF 195/558 reads (35%) | catalogued as rs755915063; called by muse, mutect2, varscan2
- SLC35F3 | c.267G>A p.L89= (on ENST00000366617 / NM_001300845.1; = p.L158= on NM_173508.4) | Silent (SNP) | VAF 340/961 reads (35%) | called by muse, mutect2, varscan2
- SLC6A3 | c.153G>A p.R51= | Silent (SNP) | VAF 419/1146 reads (37%) | called by muse, mutect2, varscan2
- SLC7A14 | c.726G>A p.A242= | Silent (SNP) | VAF 158/476 reads (33%) | catalogued as rs752901596, COSV51580118; called by muse, mutect2, varscan2
- SLC9A4 | c.2022G>A p.R674= | Silent (SNP) | VAF 94/319 reads (29%) | called by muse, varscan2
- SLIT3 | c.2256G>A p.K752= | Silent (SNP) | VAF 229/646 reads (35%) | called by muse, mutect2, varscan2
- SORL1 | c.6027G>A p.G2009= | Silent (SNP) | VAF 106/366 reads (29%) | catalogued as rs867962008; called by muse, mutect2, varscan2
- SPINK5 | c.969G>A p.G323= | Silent (SNP) | VAF 45/92 reads (49%) | called by muse, mutect2, varscan2
- SPOCD1 | c.6C>T p.S2= | Silent (SNP) | VAF 100/327 reads (31%) | called by muse, mutect2, varscan2
- SSX7 | c.27G>A p.R9= | Silent (SNP) | VAF 128/179 reads (72%) | called by muse, mutect2, varscan2
- STARD13 | c.1173G>A p.E391= (on ENST00000336934 / NM_001243476.3; = p.E273= on NM_052851.3) | Silent (SNP) | VAF 178/474 reads (38%) | catalogued as COSV55228215; called by muse, mutect2, varscan2
- STRA8 | c.675G>A p.K225= (on ENST00000275764; = p.K203= on NM_182489.2) | Silent (SNP) | VAF 914/1668 reads (55%) | called by muse, mutect2, varscan2
- TET1 | c.987C>T p.F329= | Silent (SNP) | VAF 153/331 reads (46%) | catalogued as rs531819620; called by muse, mutect2, varscan2
- TEX15 | c.2826G>A p.G942= (on ENST00000256246; = p.G1325= on NM_001350162.2) | Silent (SNP) | VAF 32/118 reads (27%) | called by muse, mutect2, varscan2
- TEX51 | c.12C>T p.L4= | Silent (SNP) | VAF 124/368 reads (34%) | called by muse, varscan2
- TFAP2C | c.519G>A p.Q173= | Silent (SNP) | VAF 237/652 reads (36%) | called by muse, mutect2, varscan2
- TH | c.177C>T p.T59= | Silent (SNP) | VAF 180/577 reads (31%) | called by muse, mutect2, varscan2
- TIAM1 | c.2862C>T p.P954= | Silent (SNP) | VAF 245/696 reads (35%) | called by muse, mutect2, varscan2
- TLCD4 | c.558C>T p.I186= | Silent (SNP) | VAF 53/195 reads (27%) | catalogued as rs779868562; called by muse, mutect2, varscan2
- TLN2 | c.4263C>T p.L1421= | Silent (SNP) | VAF 186/647 reads (29%) | catalogued as rs1290984348; called by muse, mutect2, varscan2
- TLX3 | c.168C>T p.Y56= | Silent (SNP) | VAF 536/1461 reads (37%) | catalogued as COSV99740642; called by muse, mutect2, varscan2
- TMEM119 | c.789C>T p.A263= | Silent (SNP) | VAF 255/786 reads (32%) | called by muse, mutect2, varscan2
- TNR | c.1326C>T p.F442= | Silent (SNP) | VAF 100/343 reads (29%) | catalogued as rs1418434452, COSV54878703; called by muse, mutect2, varscan2
- TNXB | c.5682G>A p.G1894= (on ENST00000647633; = p.G1647= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 187/545 reads (34%) | called by muse, mutect2, varscan2
- TOX2 | c.846C>T p.F282= (on ENST00000358131 / NM_001098798.2; = p.F231= on NM_032883.3) | Silent (SNP) | VAF 136/454 reads (30%) | catalogued as rs147266413; called by muse, mutect2, varscan2
- TRAV12-3 | c.72G>A p.K24= | Silent (SNP) | VAF 103/312 reads (33%) | called by muse, mutect2, varscan2
- TRIM29 | c.36G>A p.S12= | Silent (SNP) | VAF 312/896 reads (35%) | catalogued as rs779527495; called by muse, mutect2, varscan2
- TRIM68 | c.892C>T p.L298= | Silent (SNP) | VAF 122/372 reads (33%) | called by muse, mutect2, varscan2
- TSHZ2 | c.2091C>T p.A697= | Silent (SNP) | VAF 369/1033 reads (36%) | catalogued as COSV61592005; called by muse, mutect2, varscan2
- TTLL1 | c.1194C>T p.S398= | Silent (SNP) | VAF 201/562 reads (36%) | called by muse, mutect2, varscan2
- TTN | c.50607G>A p.R16869= (on ENST00000591111; = p.R9445= on NM_003319.4) | Silent (SNP) | VAF 138/469 reads (29%) | called by muse, mutect2, varscan2
- UBASH3A | c.1857C>T p.S619= | Silent (SNP) | VAF 128/324 reads (40%) | called by muse, mutect2, varscan2
- UBL3 | c.270C>T p.A90= | Silent (SNP) | VAF 61/221 reads (28%) | called by muse, mutect2, varscan2
- USP42 | c.3324G>A p.E1108= | Silent (SNP) | VAF 442/1241 reads (36%) | catalogued as rs904387731; called by muse, mutect2, varscan2
- VN1R2 | c.852C>T p.I284= | Silent (SNP) | VAF 190/510 reads (37%) | catalogued as rs988507744; called by muse, mutect2, varscan2
- WDR90 | c.1215C>T p.F405= | Silent (SNP) | VAF 290/805 reads (36%) | catalogued as rs1244104261; called by muse, mutect2, varscan2
- WT1 | c.1347C>T p.S449= | Silent (SNP) | VAF 236/701 reads (34%) | called by muse, mutect2, varscan2
- WWC2 | c.9G>A p.R3= | Silent (SNP) | VAF 193/534 reads (36%) | called by muse, mutect2, varscan2
- ZBTB11 | c.666A>C p.G222= | Silent (SNP) | VAF 62/203 reads (31%) | called by muse, mutect2, varscan2
- ZCCHC13 | c.138C>T p.T46= | Silent (SNP) | VAF 297/417 reads (71%) | called by muse, mutect2, varscan2
- ZKSCAN2 | c.1038G>A p.E346= | Silent (SNP) | VAF 176/539 reads (33%) | called by muse, mutect2, varscan2
- ZNF433 | c.1308C>T p.L436= | Silent (SNP) | VAF 75/299 reads (25%) | called by muse, mutect2, varscan2
- ZNF534 | c.1548C>T p.F516= (on ENST00000332323 / NM_001143939.3; = p.F503= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 100/324 reads (31%) | catalogued as rs766287174; called by muse, mutect2, varscan2
- ZNF831 | c.1455C>T p.F485= | Silent (SNP) | VAF 274/879 reads (31%) | catalogued as rs1207499907; called by muse, mutect2, varscan2
- ZNF841 | c.1974C>T p.F658= (on ENST00000426391 / NM_001369830.1; = p.F774= on NM_001136499.1 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 106/422 reads (25%) | called by muse, mutect2, varscan2
- ZNFX1 | c.1626T>C p.H542= | Silent (SNP) | VAF 142/369 reads (38%) | catalogued as rs754467723; called by muse, mutect2, varscan2
- ZP2 | c.1488C>T p.I496= | Silent (SNP) | VAF 69/243 reads (28%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1046+2967G>A | Intron (SNP) | VAF 138/466 reads (30%) | catalogued as rs1298916301; called by muse, mutect2, varscan2
- AGAP14P | n.1487C>T | RNA (SNP) | VAF 310/1181 reads (26%) | called by muse, mutect2, varscan2
- CD81 | c.67-4328C>T | Intron (SNP) | VAF 239/740 reads (32%) | catalogued as rs1012311551; called by muse, mutect2, varscan2
- DEUP1 | c.790-1790A>C | Intron (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
- EBLN3P | chr9:37079907 G>A | 5'Flank (SNP) | VAF 184/502 reads (37%) | catalogued as rs748429462; called by muse, mutect2, varscan2
- EEF1A1P17 | n.1209G>A | RNA (SNP) | VAF 99/302 reads (33%) | called by muse, mutect2, varscan2
- GLIS1 | chr1:53737825 C>T | 5'Flank (SNP) | VAF 320/941 reads (34%) | called by muse, mutect2, varscan2
- IKZF2 | c.139+18G>A | Intron (SNP) | VAF 160/452 reads (35%) | called by muse, varscan2
- KCNQ1 | c.1393+27955C>T | Intron (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
- LINC00968 | n.297C>A | RNA (SNP) | VAF 82/464 reads (18%) | called by muse, mutect2, varscan2
- LINC00968 | n.296C>T | RNA (SNP) | VAF 86/472 reads (18%) | called by muse, mutect2, varscan2
- MYO7A | c.3503+18G>A | Intron (SNP) | VAF 206/609 reads (34%) | called by muse, mutect2, varscan2
- NDEL1 | c.*184C>A | 3'UTR (SNP) | VAF 228/665 reads (34%) | called by muse, mutect2, varscan2
- OBSCN | c.11659+5021C>T | Intron (SNP) | VAF 251/459 reads (55%) | catalogued as rs747967264, COSV52827594, COSV99475197; called by muse, mutect2, varscan2
- OSTF1P1 | n.469C>T | RNA (SNP) | VAF 134/445 reads (30%) | called by muse, mutect2, varscan2
- PARP8 | c.147-5399C>T | Intron (SNP) | VAF 25/115 reads (22%) | catalogued as rs963756041; called by muse, mutect2, varscan2
- PLCH2 | c.2959+375C>T | Intron (SNP) | VAF 441/1267 reads (35%) | catalogued as rs1444959667; called by muse, mutect2, varscan2
- PPARA | c.*4845T>G | 3'UTR (SNP) | VAF 38/840 reads (5%) | called by muse, mutect2
- RAB3IL1 | chr11:61920136 G>A | 5'Flank (SNP) | VAF 274/787 reads (35%) | called by muse, mutect2, varscan2
- RASGRP3 | c.-1C>T | 5'UTR (SNP) | VAF 106/204 reads (52%) | catalogued as rs756957301; called by muse, mutect2, varscan2
- REXO1L1P | n.813C>T | RNA (SNP) | VAF 100/802 reads (12%) | catalogued as rs1263921320; called by muse, mutect2, varscan2
- RIMBP2 | c.*1660G>A | 3'UTR (SNP) | VAF 173/508 reads (34%) | catalogued as rs1214476185; called by muse, mutect2, varscan2
- RPP30 | chr10:90903245 C>T | 3'Flank (SNP) | VAF 29/52 reads (56%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-4217C>T | Intron (SNP) | VAF 123/399 reads (31%) | called by muse, mutect2, varscan2
- TBX1 | chr22:19782924 G>A | 3'Flank (SNP) | VAF 144/461 reads (31%) | catalogued as rs537289976; called by muse, mutect2, varscan2
- TSHR | c.692+120G>A | Intron (SNP) | VAF 133/373 reads (36%) | called by muse, mutect2, varscan2
- TTLL6 | c.998+1843G>A | Intron (SNP) | VAF 158/484 reads (33%) | called by muse, mutect2, varscan2
- TTN | c.34522+691C>T | Intron (SNP) | VAF 61/421 reads (14%) | called by muse, varscan2
- TTN | c.10303+2319C>T | Intron (SNP) | VAF 112/356 reads (31%) | catalogued as COSV59936808; called by muse, mutect2, varscan2
